TARGET case TARGET-30-PAAPFA — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/796cbc20-dd06-5bfb-9959-7294db4659ac

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 487 days (1.3 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 4.8 years (1,762 days); Year of diagnosis: 1986; Days to last follow up: 487 days (1.3 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Treatment given: Protocol identifier: 321P3.
   Treatment given: Protocol identifier: 321P2.
   Treatment given: Protocol identifier: E04.
   Treatment given: Protocol identifier: B954.
   Treatment given: Protocol identifier: I03.

Follow-up (2 entries)
- Days to follow up: 444 days (1.2 years); Days to first event: 444 days (1.2 years); First event: Event.
- Days to follow up: 487 days (1.3 years); Year of follow up: 1988.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.

Biospecimens (2 samples)
- Sample TARGET-30-PAAPFA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAAPFA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 487
- Protocol: I03, 321P2, E04, 321P3, B954
- Histology: Unfavorable
